Somatic mutation profile of tumor specimen TARGET-10-PASLZM-04A (aliquot TARGET-10-PASLZM-04A-01D) from TARGET case TARGET-10-PASLZM, project TARGET-ALL-P2 (Acute Lymphoblastic Leukemia - Phase II). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute lymphocytic leukemia; Tissue or organ of origin: Bone marrow; Age at diagnosis: 6.8 years (2,496 days).
Specimen TARGET-10-PASLZM-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 8f91d30f-8591-41eb-8ded-a23f1ef71182.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-10-PASLZM-10A (Blood Derived Normal), aliquot TARGET-10-PASLZM-10A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c675de41-a2e9-4987-b9a2-044f6d0ce1be

The open-access MAF lists 355 somatic variants for this specimen: 256 protein-altering or splice-affecting, 89 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 237, Silent 89, Nonsense Mutation 11, Frame Shift Ins 4, RNA 3, Splice Region 3, 3'UTR 3, 5'UTR 2, 3'Flank 2, Translation Start Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HLCS | c.1648G>A p.V550M | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs119103231, CM960835, COSV60796606; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NSD2 | c.3448A>G p.T1150A | Missense Mutation (SNP) | VAF 105/221 reads (48%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV56385908; called by muse, mutect2, varscan2
- A1CF | c.373C>T p.R125C | Missense Mutation (SNP) | VAF 41/171 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.681); catalogued as rs375285515; called by muse, mutect2, varscan2
- AASS | c.1291G>A p.A431T | Missense Mutation (SNP) | VAF 74/404 reads (18%) | SIFT tolerated (0.14); PolyPhen benign (0.031); catalogued as rs771862141, COSV62789952; called by muse, varscan2
- AC105001.2 | c.368G>A p.R123H | Missense Mutation (SNP) | VAF 154/671 reads (23%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.999); catalogued as rs369293194; called by muse, mutect2, varscan2
- ACAD9 | c.1156A>G p.S386G | Missense Mutation (SNP) | VAF 28/133 reads (21%) | SIFT tolerated (0.51); PolyPhen benign (0.229); catalogued as rs753372487, COSV58309293; called by muse, mutect2, varscan2
- ACLY | c.1183G>A p.G395R | Missense Mutation (SNP) | VAF 41/163 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.101); catalogued as COSV61252167; called by muse, mutect2, varscan2
- ACSS2 | c.1240C>T p.R414C | Missense Mutation (SNP) | VAF 39/189 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs780837244, COSV53624749; called by muse, mutect2, varscan2
- ADAMTS14 | c.2762G>A p.R921Q | Missense Mutation (SNP) | VAF 7/27 reads (26%) | SIFT tolerated (0.19); PolyPhen benign (0.069); catalogued as rs538290907, COSV64605067; called by muse, mutect2, varscan2
- ADAMTS5 | c.1607C>T p.A536V | Missense Mutation (SNP) | VAF 51/193 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.577); catalogued as rs752801493, COSV53183225; called by muse, mutect2, varscan2
- ADD3 | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.11); catalogued as COSV53324836; called by muse, mutect2, varscan2
- ADGRF5 | c.3149G>A p.R1050H | Missense Mutation (SNP) | VAF 17/92 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.923); catalogued as rs199576297, COSV51930052; called by muse, mutect2, varscan2
- ADGRV1 | c.207G>A p.S69= | Splice Region (SNP) | VAF 74/286 reads (26%) | catalogued as rs769561134, COSV67992162; called by muse, mutect2, varscan2
- AFF2 | c.3140C>T p.A1047V | Missense Mutation (SNP) | VAF 16/483 reads (3%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.778); catalogued as COSV99667056; called by muse, mutect2
- AGBL3 | c.269C>A p.P90Q | Missense Mutation (SNP) | VAF 58/534 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51956213; called by muse, mutect2, varscan2
- ANAPC11 | c.31G>A p.V11M | Missense Mutation (SNP) | VAF 42/171 reads (25%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.638); catalogued as rs1254550647, COSV58668983; called by muse, mutect2, varscan2
- APBA1 | c.1444C>T p.R482C | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs753725669, COSV55222869; called by muse, mutect2
- ARAP1 | c.3905G>A p.R1302H (on ENST00000393609 / NM_001040118.2; = p.R1057H on NM_015242.4) | Missense Mutation (SNP) | VAF 23/106 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754149945, COSV61993674; called by muse, mutect2, varscan2
- ARHGAP30 | c.2758G>A p.V920M (on ENST00000368013 / NM_001025598.2; = p.V709M on NM_181720.3) | Missense Mutation (SNP) | VAF 26/62 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as rs774114536, COSV63515698; called by muse, mutect2, varscan2
- ARHGAP33 | c.1552G>A p.G518S | Missense Mutation (SNP) | VAF 54/363 reads (15%) | SIFT tolerated, low confidence (0.17); PolyPhen possibly damaging (0.72); catalogued as rs757314465, COSV50142728; called by muse, mutect2, varscan2
- ARIH2 | c.1390G>A p.A464T | Missense Mutation (SNP) | VAF 39/256 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV62705830; called by muse, mutect2, varscan2
- ATF7IP | c.1873C>T p.R625* | Nonsense Mutation (SNP) | VAF 115/441 reads (26%) | catalogued as COSV53773349; called by muse, mutect2, varscan2
- ATG16L1 | c.548C>A p.T183N | Missense Mutation (SNP) | VAF 42/179 reads (23%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV61467222; called by muse, mutect2, varscan2
- ATP11A | c.1079T>C p.I360T | Missense Mutation (SNP) | VAF 55/199 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52119601; called by muse, mutect2, varscan2
- ATP11C | c.1073T>C p.I358T | Missense Mutation (SNP) | VAF 38/240 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59570341; called by muse, mutect2, varscan2
- BCL2A1 | c.412G>A p.G138R | Missense Mutation (SNP) | VAF 89/360 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1472374244, COSV51213429, COSV51213657; called by muse, mutect2, varscan2
- BRPF3 | c.731A>G p.Y244C | Missense Mutation (SNP) | VAF 53/180 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60208994; called by muse, mutect2, varscan2
- C3orf20 | c.188C>T p.P63L | Missense Mutation (SNP) | VAF 31/234 reads (13%) | SIFT tolerated (0.08); PolyPhen benign (0.332); catalogued as rs764690622, COSV53784823; called by muse, mutect2, varscan2
- CA11 | c.916C>T p.R306W | Missense Mutation (SNP) | VAF 7/26 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV50033830; called by muse, mutect2, varscan2
- CAD | c.587G>A p.R196H | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.714); catalogued as rs144305066; called by muse, mutect2, varscan2
- CARMIL3 | c.1852G>A p.A618T | Missense Mutation (SNP) | VAF 57/219 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs1158902521, COSV57727800; called by muse, mutect2, varscan2
- CCDC88B | c.1343C>T p.S448L | Missense Mutation (SNP) | VAF 45/151 reads (30%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as rs1368935751, COSV57267199; called by muse, mutect2, varscan2
- CDCP1 | c.511G>A p.V171M | Missense Mutation (SNP) | VAF 32/168 reads (19%) | SIFT tolerated (0.17); PolyPhen benign (0.006); catalogued as rs779637766, COSV56107183; called by muse, mutect2, varscan2
- CDH18 | c.2063G>A p.R688Q | Missense Mutation (SNP) | VAF 92/296 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.627); catalogued as rs140353037; called by muse, varscan2
- CEP135 | c.2368C>T p.R790C | Missense Mutation (SNP) | VAF 59/236 reads (25%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs138305619; called by muse, mutect2, varscan2
- CEP192 | c.3853G>A p.A1285T | Missense Mutation (SNP) | VAF 11/209 reads (5%) | SIFT tolerated (0.38); PolyPhen benign (0.007); catalogued as COSV58068686; called by muse, mutect2
- CHIA | c.1240G>A p.G414R (on ENST00000343320; = p.G306R on NM_021797.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 25/98 reads (26%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as rs199811046, COSV58477303; called by muse, mutect2, varscan2
- CHRM4 | c.991C>T p.R331W | Missense Mutation (SNP) | VAF 24/97 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.892); catalogued as rs200850651, COSV63125958; called by muse, mutect2, varscan2
- CHRM5 | c.416G>A p.R139Q | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372901279; called by muse, mutect2, varscan2
- CLASP2 | c.2903C>T p.A968V (on ENST00000359576; = p.A967V on NM_015097.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 346/737 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.952); catalogued as rs373215296; called by muse, mutect2, varscan2
- CNKSR1 | c.1679G>A p.R560H (on ENST00000374253 / NM_001297647.2; = p.R553H on NM_006314.3) | Missense Mutation (SNP) | VAF 16/85 reads (19%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs148602031; called by muse, mutect2, varscan2
- CNNM4 | c.688C>T p.R230C | Missense Mutation (SNP) | VAF 68/145 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs147976284; called by muse, mutect2, varscan2
- COL1A2 | c.2716C>T p.R906C | Missense Mutation (SNP) | VAF 125/704 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs1384188360, COSV51963467; called by muse, mutect2, varscan2
- COL26A1 | c.919C>T p.R307W (on ENST00000313669 / NM_001278563.3; = p.R305W on NM_133457.4) | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.928); catalogued as rs750199521, COSV58129795; called by muse, mutect2, varscan2
- COL4A4 | c.4151C>T p.A1384V | Missense Mutation (SNP) | VAF 23/90 reads (26%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs199911379; called by muse, mutect2, varscan2
- COL5A2 | c.383G>A p.R128H | Missense Mutation (SNP) | VAF 94/367 reads (26%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.991); catalogued as rs757439328, COSV66411929; called by muse, mutect2, varscan2
- CREB5 | c.1151G>A p.R384Q (on ENST00000357727 / NM_182898.4; = p.R377Q on NM_004904.3) | Missense Mutation (SNP) | VAF 7/61 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63226382; called by muse, mutect2, varscan2
- CSMD2 | c.1451C>T p.P484L | Missense Mutation (SNP) | VAF 65/234 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs917413256, COSV53944330; called by muse, mutect2, varscan2
- CSMD3 | c.10172G>A p.R3391H (on ENST00000297405 / NM_001363185.1; = p.R3222H on NM_052900.3) | Missense Mutation (SNP) | VAF 80/329 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs750171856, COSV52100044, COSV52183749; called by muse, mutect2, varscan2
- CSPG4 | c.3589G>A p.V1197I | Missense Mutation (SNP) | VAF 10/48 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs774099952, COSV57899615; called by muse, mutect2, varscan2
- CWC22 | c.266G>A p.R89Q | Missense Mutation (SNP) | VAF 15/446 reads (3%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.652); catalogued as rs1264975382; called by muse, mutect2
- CYP2C8 | c.782G>A p.R261Q | Missense Mutation (SNP) | VAF 174/616 reads (28%) | SIFT tolerated (0.2); PolyPhen benign (0.193); catalogued as rs370459834, COSV64878388; called by muse, mutect2, varscan2
- CYTIP | c.931G>A p.G311R | Missense Mutation (SNP) | VAF 38/164 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.579); catalogued as COSV51635200; called by muse, mutect2, varscan2
- DAB2IP | c.39C>T p.Y13= | Splice Region (SNP) | VAF 21/78 reads (27%) | catalogued as rs201252302, COSV52255139; called by muse, mutect2, varscan2
- DDX41 | c.466T>C p.S156P | Missense Mutation (SNP) | VAF 14/281 reads (5%) | SIFT tolerated (0.46); PolyPhen benign (0.003); catalogued as COSV57905128; called by muse, mutect2
- DDX46 | c.2217A>C p.E739D | Missense Mutation (SNP) | VAF 65/320 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.093); catalogued as COSV62800532; called by muse, mutect2, varscan2
- DNAH6 | c.5464C>T p.R1822* | Nonsense Mutation (SNP) | VAF 59/265 reads (22%) | catalogued as rs543133441, COSV52876000; called by muse, mutect2, varscan2
- DNAH6 | c.9633A>C p.K3211N | Missense Mutation (SNP) | VAF 74/533 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.356); catalogued as COSV52876028; called by muse, mutect2, varscan2
- DNAH8 | c.7627C>T p.R2543* | Nonsense Mutation (SNP) | VAF 62/205 reads (30%) | catalogued as rs776257226, COSV59436895; called by muse, mutect2, varscan2
- DNAH9 | c.9880G>A p.A3294T | Missense Mutation (SNP) | VAF 13/101 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.097); catalogued as rs368607572; called by muse, mutect2, varscan2
- DROSHA | c.2611C>T p.R871C | Missense Mutation (SNP) | VAF 69/292 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.775); catalogued as rs372313396; called by muse, mutect2, varscan2
- DSCAM | c.2348C>T p.T783M | Missense Mutation (SNP) | VAF 53/217 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.708); catalogued as rs760068335, COSV68026595; called by muse, mutect2, varscan2
- DSCAML1 | c.3845G>A p.R1282H (on ENST00000321322; = p.R1222H on NM_020693.4) | Missense Mutation (SNP) | VAF 12/68 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.979); catalogued as rs769756412, COSV58398958; called by muse, mutect2, varscan2
- DSG3 | c.145C>T p.R49C | Missense Mutation (SNP) | VAF 61/316 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs776376388, COSV57128448; called by muse, mutect2, varscan2
- DUOX2 | c.4537G>A p.G1513R | Missense Mutation (SNP) | VAF 32/187 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748262140, COSV66533564; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DUSP18 | c.235C>G p.L79V | Missense Mutation (SNP) | VAF 117/284 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); catalogued as COSV58181379; called by muse, mutect2, varscan2
- EDF1 | c.188G>A p.R63Q | Missense Mutation (SNP) | VAF 109/496 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.427); catalogued as rs1046507869, COSV56376911; called by muse, mutect2, varscan2
- EFR3B | c.2222G>A p.R741H | Missense Mutation (SNP) | VAF 8/138 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.835); catalogued as rs894458724; called by muse, mutect2
- EIF4G1 | c.2024G>A p.R675Q (on ENST00000346169 / NM_198241.3; = p.R479Q on NM_004953.5) | Missense Mutation (SNP) | VAF 59/266 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.517); catalogued as rs777304254, COSV59992857; called by muse, mutect2, varscan2
- ENPP6 | c.809G>A p.R270H | Missense Mutation (SNP) | VAF 66/227 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.269); catalogued as rs201276870, COSV57070703; called by muse, mutect2, varscan2
- ERAP2 | c.1207G>A p.A403T | Missense Mutation (SNP) | VAF 98/701 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.244); catalogued as rs757058709, COSV65940904; called by muse, mutect2, varscan2
- ERN2 | c.721C>T p.R241C | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.776); catalogued as rs773081932; called by muse, varscan2
- FAM117A | c.878C>T p.A293V | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs781624561; called by muse, varscan2
- FAM124A | c.583C>T p.R195W (on ENST00000322475 / NM_001242312.2; = p.R231W on NM_145019.4) | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.804); catalogued as rs1054359983, COSV54474942; called by muse, mutect2, varscan2
- FAM135B | c.1169C>T p.P390L | Missense Mutation (SNP) | VAF 37/141 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs767500178, COSV52744495, COSV52754574, COSV52759780; called by muse, mutect2, varscan2
- FAM20A | c.526C>T p.R176W | Missense Mutation (SNP) | VAF 22/200 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs149777674, COSV56835629; called by muse, mutect2, varscan2
- FBXL18 | c.845T>C p.L282P | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.929); catalogued as COSV66668016; called by muse, mutect2, varscan2
- FGF2 | c.715C>T p.R239* | Nonsense Mutation (SNP) | VAF 127/583 reads (22%) | catalogued as COSV52648737; called by muse, mutect2, varscan2
- FLG | c.4966C>T p.R1656C | Missense Mutation (SNP) | VAF 85/181 reads (47%) | SIFT tolerated (0.14); PolyPhen benign (0.353); catalogued as rs775926509, COSV64245932, COSV64246281; called by muse, mutect2, varscan2
- FLNC | c.3500G>A p.R1167H | Missense Mutation (SNP) | VAF 17/88 reads (19%) | SIFT tolerated (0.2); PolyPhen benign (0.014); catalogued as rs574074583, COSV57950237; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- FMNL3 | c.605G>A p.R202Q | Missense Mutation (SNP) | VAF 25/104 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.979); catalogued as rs1244619926, COSV53298936, COSV53305880; called by muse, mutect2, varscan2
- FNBP1L | c.505G>A p.E169K | Missense Mutation (SNP) | VAF 34/442 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53095595; called by muse, mutect2
- FNIP2 | c.1400G>A p.R467H | Missense Mutation (SNP) | VAF 71/262 reads (27%) | SIFT tolerated (1); PolyPhen benign (0.065); catalogued as rs770340453, COSV52443825; called by muse, mutect2, varscan2
- GABBR2 | c.1066G>A p.G356R | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52303572; called by muse, mutect2
- GDAP1 | c.928C>T p.R310W | Missense Mutation (SNP) | VAF 49/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs538389475, CD1411841, COSV55186723; called by muse, mutect2, varscan2
- GDE1 | c.652C>T p.R218W | Missense Mutation (SNP) | VAF 84/586 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.606); catalogued as rs757733912, COSV62059355, COSV62059713; called by muse, varscan2
- GKN1 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 37/162 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.012); catalogued as rs374864826, COSV65006240; called by muse, mutect2, varscan2
- GRHL2 | c.1111G>A p.V371M | Missense Mutation (SNP) | VAF 49/208 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs779974367, COSV52552647; called by muse, mutect2, varscan2
- GRIA1 | c.1057G>A p.V353M | Missense Mutation (SNP) | VAF 58/200 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs763067443, COSV53617172; called by muse, mutect2, varscan2
- GRID1 | c.1516G>A p.G506R | Missense Mutation (SNP) | VAF 44/181 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1261175074, COSV60042983, COSV60044903; called by muse, mutect2, varscan2
- GRIN2A | c.4355G>A p.R1452H | Missense Mutation (SNP) | VAF 42/233 reads (18%) | SIFT tolerated (0.64); PolyPhen probably damaging (0.998); catalogued as rs774039446, COSV58020621; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GTF2I | c.31G>A p.V11I | Missense Mutation (SNP) | VAF 42/403 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0); catalogued as rs782542929, COSV60401510; called by muse, mutect2, varscan2
- HCRTR2 | c.623C>T p.T208M | Missense Mutation (SNP) | VAF 50/162 reads (31%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.745); catalogued as rs200545298, COSV63795564; called by muse, mutect2, varscan2
- HECTD4 | c.5648A>G p.E1883G | Missense Mutation (SNP) | VAF 33/114 reads (29%) | SIFT tolerated (0.11); PolyPhen benign (0.06); catalogued as COSV66397087; called by muse, mutect2, varscan2
- HOXB3 | c.1244C>T p.A415V | Missense Mutation (SNP) | VAF 74/522 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.833); catalogued as COSV57485694; called by mutect2, varscan2
- HS3ST1 | c.365C>T p.A122V | Missense Mutation (SNP) | VAF 3/22 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.975); catalogued as COSV50022972; called by muse, mutect2
- IL16 | c.1198C>T p.R400W | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT deleterious (0.02); PolyPhen benign (0.07); catalogued as rs367823776; called by muse, mutect2, varscan2
- IL36A | c.385G>A p.A129T | Missense Mutation (SNP) | VAF 39/164 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.872); catalogued as rs778385663, COSV52083640; called by muse, mutect2, varscan2
- ING3 | c.890G>A p.R297Q | Missense Mutation (SNP) | VAF 40/235 reads (17%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs768333923, COSV59951863; called by muse, mutect2, varscan2
- INPP5K | c.1288C>T p.Q430* | Nonsense Mutation (SNP) | VAF 29/128 reads (23%) | catalogued as COSV57442137; called by muse, mutect2, varscan2
- ITIH3 | c.740A>G p.D247G | Missense Mutation (SNP) | VAF 107/418 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.992); catalogued as COSV69649840; called by muse, mutect2, varscan2
- KANK4 | c.2470G>A p.G824R | Missense Mutation (SNP) | VAF 20/85 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs1213102522, COSV58092037; called by muse, mutect2, varscan2
- KDELR2 | c.476G>A p.R159H | Missense Mutation (SNP) | VAF 65/155 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51727489; called by muse, mutect2, varscan2
- KDM5B | c.1391T>C p.M464T | Missense Mutation (SNP) | VAF 28/134 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.212); catalogued as COSV52511095; called by muse, mutect2, varscan2
- KIAA1210 | c.934C>T p.R312* | Nonsense Mutation (SNP) | VAF 148/516 reads (29%) | catalogued as COSV68179049; called by muse, mutect2, varscan2
- KIAA1217 | c.980C>T p.P327L | Missense Mutation (SNP) | VAF 66/228 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267602445; called by muse, mutect2, varscan2
- KIAA1217 | c.2110C>T p.R704C | Missense Mutation (SNP) | VAF 53/206 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764228256, COSV56816477; called by muse, mutect2, varscan2
- KIAA1755 | c.187C>T p.R63* | Nonsense Mutation (SNP) | VAF 14/52 reads (27%) | catalogued as rs771068405, COSV54079279; called by muse, mutect2, varscan2
- KLK6 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 107/466 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.086); catalogued as rs750796134, COSV59566394; called by muse, mutect2, varscan2
- KPNA7 | c.201G>A p.A67= | Splice Region (SNP) | VAF 81/472 reads (17%) | catalogued as rs756748750, COSV59399932; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LAMB2 | c.986G>A p.R329H | Missense Mutation (SNP) | VAF 26/175 reads (15%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs909274897, COSV59736412; called by muse, mutect2, varscan2
- LCN8 | c.349C>T p.R117W (on ENST00000612714 / NM_001345934.1; = p.R94W on NM_178469.3) | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as rs149375049; called by muse, mutect2
- LIFR | c.2579G>A p.R860Q | Missense Mutation (SNP) | VAF 46/166 reads (28%) | SIFT tolerated (0.14); PolyPhen benign (0.166); catalogued as rs765499626, COSV54692351; called by muse, mutect2, varscan2
- LPO | c.1394G>A p.R465H | Missense Mutation (SNP) | VAF 45/207 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.966); catalogued as rs140718738, COSV51858487; called by muse, mutect2, varscan2
- LRFN2 | c.49G>A p.V17M | Missense Mutation (SNP) | VAF 6/32 reads (19%) | SIFT tolerated (0.44); PolyPhen benign (0.003); catalogued as rs770797333, COSV57824900; called by muse, mutect2, varscan2
- LRRN3 | c.2074A>G p.T692A | Missense Mutation (SNP) | VAF 24/304 reads (8%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV57822675; called by muse, mutect2
- MAGEC3 | c.127C>T p.R43W | Missense Mutation (SNP) | VAF 101/341 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.061); catalogued as rs370315828, COSV74217389; called by muse, mutect2, varscan2
- MAP3K13 | c.2770A>G p.K924E | Missense Mutation (SNP) | VAF 20/130 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen possibly damaging (0.452); catalogued as COSV53994116; called by muse, mutect2, varscan2
- MAP3K21 | c.1169C>T p.S390L | Missense Mutation (SNP) | VAF 60/228 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.581); catalogued as rs753079246, COSV64045846; called by muse, mutect2, varscan2
- MARCHF10 | c.730A>G p.S244G | Missense Mutation (SNP) | VAF 57/184 reads (31%) | SIFT tolerated (0.6); PolyPhen benign (0.001); catalogued as COSV60889632; called by muse, mutect2, varscan2
- MARF1 | c.4148C>T p.S1383L | Missense Mutation (SNP) | VAF 71/185 reads (38%) | SIFT tolerated (0.53); PolyPhen benign (0.007); catalogued as rs779042389, COSV60027314; called by muse, mutect2, varscan2
- MARS2 | c.1090C>T p.R364C | Missense Mutation (SNP) | VAF 10/280 reads (4%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.773); catalogued as rs1337059237; called by muse, mutect2
- MARVELD2 | c.1099A>G p.R367G | Missense Mutation (SNP) | VAF 22/116 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV57781799; called by muse, mutect2, varscan2
- MARVELD2 | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 42/216 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.117); catalogued as COSV57781814; called by muse, mutect2, varscan2
- MATN1 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs749407303, COSV65651195; called by muse, mutect2, varscan2
- MBD6 | c.2828C>T p.P943L | Missense Mutation (SNP) | VAF 112/443 reads (25%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0); catalogued as rs374027869, CM1212436, COSV63075508; called by muse, mutect2, varscan2
- MBNL1 | c.343G>A p.V115M | Missense Mutation (SNP) | VAF 45/252 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0.039); catalogued as rs754733825, COSV56833437; called by muse, mutect2, varscan2
- MCUB | c.160G>A p.V54M | Missense Mutation (SNP) | VAF 82/616 reads (13%) | SIFT deleterious (0.04); PolyPhen benign (0.301); catalogued as rs905974756, COSV67120048; called by muse, varscan2
- MED13 | c.5756C>T p.P1919L | Missense Mutation (SNP) | VAF 66/242 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs770097254, COSV67265969; called by muse, mutect2, varscan2
- MOCOS | c.2401C>T p.R801C | Missense Mutation (SNP) | VAF 69/524 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.809); catalogued as rs371356274; called by muse, mutect2, varscan2
- MOV10 | c.440G>A p.R147H | Missense Mutation (SNP) | VAF 60/235 reads (26%) | SIFT tolerated (0.16); PolyPhen benign (0); catalogued as rs770092703, COSV62490600; called by muse, mutect2, varscan2
- MOV10L1 | c.2434C>T p.R812W | Missense Mutation (SNP) | VAF 61/254 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs763534299, COSV53176776; called by muse, mutect2, varscan2
- MPDZ | c.1844T>C p.V615A | Missense Mutation (SNP) | VAF 97/522 reads (19%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.841); catalogued as COSV59949704; called by muse, mutect2, varscan2
- MRGPRX1 | c.170G>A p.R57H | Missense Mutation (SNP) | VAF 17/161 reads (11%) | SIFT tolerated (0.4); PolyPhen benign (0.013); catalogued as COSV57106647, COSV57108814; called by muse, mutect2, varscan2
- MRPS23 | c.167C>T p.A56V | Missense Mutation (SNP) | VAF 34/159 reads (21%) | SIFT tolerated (0.36); PolyPhen possibly damaging (0.474); catalogued as COSV58032741; called by muse, mutect2, varscan2
- MTHFD1 | c.361G>A p.E121K | Missense Mutation (SNP) | VAF 70/431 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.06); catalogued as rs749742870, COSV53699749, COSV53701614; called by muse, mutect2, varscan2
- MUC2 | c.1906G>A p.A636T | Missense Mutation (SNP) | VAF 14/45 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.415); catalogued as rs759459498; called by muse, mutect2, varscan2
- MXRA5 | c.6206G>A p.C2069Y | Missense Mutation (SNP) | VAF 33/59 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54245117; called by muse, mutect2, varscan2
- MYBPH | c.1150T>C p.F384L | Missense Mutation (SNP) | VAF 41/299 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs574620213, COSV55143694; called by muse, mutect2, varscan2
- MYO1A | c.1855C>T p.R619W | Missense Mutation (SNP) | VAF 14/73 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs754370052, COSV55656416; called by muse, mutect2, varscan2
- MYO5B | c.2432G>A p.R811Q | Missense Mutation (SNP) | VAF 8/74 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.394); catalogued as rs772254605, COSV99546683; called by muse, mutect2, varscan2
- MYORG | c.2035G>A p.A679T | Missense Mutation (SNP) | VAF 9/35 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.616); catalogued as COSV52626861; called by muse, mutect2, varscan2
- NAT1 | c.364G>A p.D122N | Missense Mutation (SNP) | VAF 21/182 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56985020; called by muse, mutect2, varscan2
- NEDD9 | c.1472G>A p.R491Q | Missense Mutation (SNP) | VAF 50/234 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs780340745, COSV65222602; called by muse, mutect2, varscan2
- NEK10 | c.1832C>T p.P611L | Missense Mutation (SNP) | VAF 116/482 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.524); catalogued as rs746525740, COSV58281740; called by muse, varscan2
- NMU | c.188C>T p.S63L | Missense Mutation (SNP) | VAF 87/376 reads (23%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as rs753988049, COSV51698744; called by muse, mutect2, varscan2
- NR6A1 | c.197G>A p.R66H (on ENST00000487099 / NM_033334.4; = p.R62H on NM_001489.5) | Missense Mutation (SNP) | VAF 25/108 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs771035345, COSV60633711; called by muse, mutect2, varscan2
- NTRK2 | c.1981G>A p.A661T (on ENST00000323115 / NM_001369534.1; = p.A677T on NM_006180.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/68 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1406280648, COSV52857586; called by muse, mutect2, varscan2
- OBSCN | c.10028C>T p.S3343L | Missense Mutation (SNP) | VAF 46/170 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.364); catalogued as rs751072511, COSV52809780; called by mutect2, varscan2
- OR4S1 | c.589G>A p.V197M | Missense Mutation (SNP) | VAF 50/269 reads (19%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.85); catalogued as rs777534434, COSV60679707; called by muse, varscan2
- OR51F1 | c.824G>A p.R275Q | Missense Mutation (SNP) | VAF 34/164 reads (21%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs536873822, COSV58580427; called by muse, varscan2
- OR51F1 | c.778T>C p.F260L | Missense Mutation (SNP) | VAF 30/144 reads (21%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV58580446; called by muse, varscan2
- OR5A2 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs748854856, COSV57391599; called by muse, mutect2, varscan2
- PARD3 | c.1273G>A p.A425T | Missense Mutation (SNP) | VAF 37/225 reads (16%) | SIFT tolerated (0.41); PolyPhen benign (0); catalogued as rs547955907, COSV60749757; called by muse, mutect2, varscan2
- PCDH15 | c.4766G>A p.R1589H (on ENST00000644397 / NM_001354429.2; = p.R1531H on NM_001142771.2) | Missense Mutation (SNP) | VAF 31/137 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.787); catalogued as rs565739662, COSV64720102; called by muse, mutect2, varscan2
- PCDHAC1 | c.2396G>A p.R799Q | Missense Mutation (SNP) | VAF 51/204 reads (25%) | SIFT tolerated (0.35); PolyPhen benign (0.003); catalogued as rs386352346, COSV53863427, COSV53873987; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PCDHAC2 | c.1072G>A p.V358M | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); catalogued as COSV53863442; called by muse, mutect2, varscan2
- PCDHB7 | c.685C>T p.R229C | Missense Mutation (SNP) | VAF 30/114 reads (26%) | SIFT deleterious, low confidence (0.03); PolyPhen possibly damaging (0.901); catalogued as COSV50758731; called by muse, mutect2, varscan2
- PCDHGA6 | c.133G>A p.V45I | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.954); catalogued as rs745786041, COSV54003399; called by muse, mutect2, varscan2
- PCDHGB5 | c.1513G>A p.A505T | Missense Mutation (SNP) | VAF 8/59 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.509); catalogued as COSV54003416; called by muse, mutect2, varscan2
- PCOLCE | c.1173dup p.M392Hfs*81 | Frame Shift Ins (INS) | VAF 52/346 reads (15%) | catalogued as rs777844367; called by mutect2, varscan2
- PKP2 | c.971C>T p.A324V | Missense Mutation (SNP) | VAF 14/50 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs529523595, CD136706, COSV50741576; called by muse, mutect2, varscan2
- PLCXD1 | c.724G>A p.G242S | Missense Mutation (SNP) | VAF 35/127 reads (28%) | SIFT tolerated (0.05); PolyPhen benign (0.445); catalogued as rs752771178, COSV67542396; called by muse, mutect2, varscan2
- POLD1 | c.1054C>T p.R352C | Missense Mutation (SNP) | VAF 13/36 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.189); catalogued as rs762330164, COSV70954244; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PRKCD | c.671G>A p.R224H | Missense Mutation (SNP) | VAF 59/209 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1553668239, COSV57850413; called by muse, mutect2, varscan2
- PSAPL1 | c.1165G>A p.A389T | Missense Mutation (SNP) | VAF 9/36 reads (25%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as rs777223493, COSV59844087; called by muse, mutect2, varscan2
- PSMD13 | c.653T>C p.M218T | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.044); catalogued as rs1379115732, COSV61501564; called by muse, mutect2, varscan2
- PTGER3 | c.251G>A p.R84H | Missense Mutation (SNP) | VAF 8/41 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.983); catalogued as rs1282118933, COSV60689024; called by muse, mutect2, varscan2
- PTPRN | c.262C>T p.R88* | Nonsense Mutation (SNP) | VAF 24/108 reads (22%) | catalogued as COSV55345328; called by muse, mutect2, varscan2
- PUS7 | c.1724G>A p.R575Q | Missense Mutation (SNP) | VAF 133/833 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs756280222, COSV62676323; called by muse, mutect2, varscan2
- PYGO2 | c.304G>A p.G102R | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV63757459; called by muse, mutect2, varscan2
- RAD21 | c.166T>C p.S56P | Missense Mutation (SNP) | VAF 165/365 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV52062241; called by muse, mutect2, varscan2
- RASGRP3 | c.581C>T p.S194L | Missense Mutation (SNP) | VAF 47/318 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.701); catalogued as rs904208199, COSV67824174; called by muse, mutect2, varscan2
- RBSN | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs773052562, COSV53794840; called by muse, mutect2, varscan2
- REPIN1 | c.107G>A p.R36H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as rs201119833, COSV68292786; called by muse, mutect2, varscan2
- REPS2 | c.445C>T p.R149* | Nonsense Mutation (SNP) | VAF 14/372 reads (4%) | catalogued as rs1197091922; called by muse, mutect2
- RETN | c.106G>A p.A36T | Missense Mutation (SNP) | VAF 32/138 reads (23%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as rs372142945; called by muse, mutect2, varscan2
- RNASEL | c.395C>T p.A132V | Missense Mutation (SNP) | VAF 5/95 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.548); catalogued as rs1358619042; called by muse, mutect2
- RNF148 | c.454G>A p.A152T | Missense Mutation (SNP) | VAF 36/373 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.971); catalogued as rs200865337; called by muse, mutect2
- RNF208 | c.524A>G p.Y175C | Missense Mutation (SNP) | VAF 16/77 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.97); catalogued as COSV61289482; called by muse, mutect2
- RNF8 | c.1236G>T p.E412D | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57722025; called by muse, mutect2, varscan2
- RP1 | c.10A>G p.T4A | Missense Mutation (SNP) | VAF 43/269 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.898); catalogued as COSV55123395; called by muse, mutect2, varscan2
- RSBN1 | c.787C>T p.R263* | Nonsense Mutation (SNP) | VAF 78/359 reads (22%) | catalogued as COSV54731089, COSV54734389, COSV99793496; called by muse, mutect2, varscan2
- RXFP3 | c.178G>A p.A60T | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.06); PolyPhen benign (0.003); catalogued as COSV57505673; called by muse, mutect2, varscan2
- SAMD11 | c.1876C>T p.R626W | Missense Mutation (SNP) | VAF 8/18 reads (44%) | SIFT deleterious (0); PolyPhen possibly damaging (0.763); catalogued as rs749874826, COSV58990097; called by muse, mutect2, varscan2
- SCLY | c.823G>A p.A275T (on ENST00000651534; = p.A267T on NM_016510.7) | Missense Mutation (SNP) | VAF 105/506 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV54543328; called by muse, mutect2, varscan2
- SENP1 | c.1094C>T p.A365V | Missense Mutation (SNP) | VAF 23/416 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as COSV50301101; called by muse, mutect2
- SERPINB4 | c.1057G>A p.E353K | Missense Mutation (SNP) | VAF 49/218 reads (22%) | SIFT tolerated (0.93); PolyPhen benign (0.006); catalogued as rs764188105, COSV61984169; called by muse, mutect2, varscan2
- SETD1B | c.3314A>G p.D1105G | Missense Mutation (SNP) | VAF 14/83 reads (17%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as COSV57353070; called by muse, mutect2, varscan2
- SGSH | c.1037G>A p.R346Q | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT tolerated (0.07); PolyPhen benign (0.104); catalogued as rs367883023, COSV58340223; called by muse, mutect2
- SH3RF1 | c.280A>G p.T94A | Missense Mutation (SNP) | VAF 19/96 reads (20%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV52923715; called by muse, mutect2, varscan2
- SLC38A5 | c.556G>A p.A186T | Missense Mutation (SNP) | VAF 13/407 reads (3%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.946); catalogued as COSV58334882; called by muse, mutect2
- SLC4A8 | c.1393T>C p.W465R | Missense Mutation (SNP) | VAF 38/244 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.288); catalogued as rs778843909, COSV60656754; called by muse, mutect2
- SORCS3 | c.2431G>A p.A811T | Missense Mutation (SNP) | VAF 17/118 reads (14%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.878); catalogued as rs758509763, COSV63793290; called by muse, mutect2, varscan2
- SPTA1 | c.4420C>T p.R1474W | Missense Mutation (SNP) | VAF 101/438 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.424); catalogued as rs368042757, COSV63752884; called by muse, mutect2, varscan2
- SPTBN5 | c.520G>A p.A174T | Missense Mutation (SNP) | VAF 26/80 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.244); catalogued as rs758116559, COSV58016475; called by muse, mutect2, varscan2
- SRCIN1 | c.2318C>T p.S773L (on ENST00000621492; = p.S739L on NM_025248.3) | Missense Mutation (SNP) | VAF 28/119 reads (24%) | SIFT tolerated (0.62); PolyPhen probably damaging (0.975); catalogued as rs775322298; called by muse, mutect2, varscan2
- SSTR4 | c.163G>A p.A55T | Missense Mutation (SNP) | VAF 10/43 reads (23%) | SIFT tolerated (0.31); PolyPhen benign (0.087); catalogued as rs749577596, COSV54799500; called by muse, mutect2, varscan2
- STAB2 | c.1856A>G p.N619S | Missense Mutation (SNP) | VAF 62/475 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.371); catalogued as COSV66344236; called by muse, mutect2, varscan2
- STARD8 | c.2603A>G p.E868G | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV52930454; called by muse, mutect2, varscan2
- STAT1 | c.1840T>C p.F614L | Missense Mutation (SNP) | VAF 19/56 reads (34%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.556); catalogued as COSV63117146; called by muse, varscan2
- STAT1 | c.1757G>A p.R586Q | Missense Mutation (SNP) | VAF 14/60 reads (23%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as rs144788879; ClinVar: uncertain significance; called by muse, varscan2
- STAT5B | c.2155G>A p.G719R | Missense Mutation (SNP) | VAF 29/89 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.181); catalogued as rs1269922038, COSV53184270, COSV53185067, COSV99510639; called by muse, mutect2, varscan2
- STK11IP | c.1882C>T p.R628C | Missense Mutation (SNP) | VAF 41/177 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1003766827, COSV55253723; called by muse, mutect2, varscan2
- STRA8 | c.535G>A p.A179T (on ENST00000275764; = p.A157T on NM_182489.2) | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT tolerated (0.6); PolyPhen benign (0.089); catalogued as COSV51960937; called by muse, mutect2, varscan2
- STRADA | c.997C>T p.R333W (on ENST00000336174 / NM_001363786.1; = p.R296W on NM_153335.6) | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.916); catalogued as rs761989598, COSV51992441; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE1 | c.7138C>T p.R2380C (on ENST00000367255 / NM_182961.4; = p.R2387C on NM_033071.3) | Missense Mutation (SNP) | VAF 94/365 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.115); catalogued as rs1029302917, COSV55050929; called by muse, mutect2, varscan2
- TACR3 | c.1252G>A p.A418T | Missense Mutation (SNP) | VAF 20/390 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0); catalogued as COSV59205999; called by muse, mutect2
- TAF3 | c.586C>T p.R196W | Missense Mutation (SNP) | VAF 36/142 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.712); catalogued as COSV60209937; called by muse, mutect2, varscan2
- TARBP1 | c.3242G>A p.R1081H | Missense Mutation (SNP) | VAF 64/281 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV50180342; called by muse, mutect2, varscan2
- TBATA | c.598G>A p.G200S | Missense Mutation (SNP) | VAF 32/116 reads (28%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs376093383; called by muse, mutect2, varscan2
- TBC1D17 | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 62/258 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs374232022; called by muse, varscan2
- TCF12 | c.896G>A p.R299H | Missense Mutation (SNP) | VAF 124/459 reads (27%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.906); catalogued as rs202035941, COSV51014232; called by muse, mutect2, varscan2
- TDRD12 | c.253G>A p.A85T | Missense Mutation (SNP) | VAF 152/608 reads (25%) | SIFT tolerated (0.25); PolyPhen benign (0.339); catalogued as rs1305879579, COSV70015483; called by muse, mutect2, varscan2
- TENT5C | c.71G>A p.R24Q | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.916); catalogued as COSV65616854; called by muse, mutect2, varscan2
- TLN2 | c.5024G>A p.R1675Q | Missense Mutation (SNP) | VAF 17/56 reads (30%) | SIFT tolerated (0.14); PolyPhen benign (0.088); catalogued as rs372775961, COSV100168791; called by muse, mutect2, varscan2
- TMEM120B | c.575A>G p.H192R | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV61185279; called by muse, mutect2
- TMEM181 | c.880G>A p.A294T | Missense Mutation (SNP) | VAF 36/443 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.345); catalogued as rs368999298; called by muse, mutect2
- TMEM201 | c.557T>C p.L186S | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61052377; called by muse, mutect2, varscan2
- TNRC6B | c.157G>A p.A53T | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.274); catalogued as rs765835653, COSV57287804; called by muse, mutect2
- TREM1 | c.379G>A p.D127N | Missense Mutation (SNP) | VAF 23/105 reads (22%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as rs748711105, COSV55149353; called by muse, mutect2, varscan2
- TRPM2 | c.2962G>A p.G988S | Missense Mutation (SNP) | VAF 30/91 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.627); catalogued as rs757441917, COSV55966806; called by muse, mutect2, varscan2
- TRPM4 | c.1310G>A p.R437Q | Missense Mutation (SNP) | VAF 49/187 reads (26%) | SIFT deleterious (0.03); PolyPhen benign (0.219); catalogued as rs149806315; called by muse, mutect2, varscan2
- TSHZ1 | c.1412C>T p.P471L (on ENST00000580243 / NM_001308210.2; = p.P426L on NM_005786.6) | Missense Mutation (SNP) | VAF 29/103 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.416); catalogued as rs142270240; called by muse, mutect2, varscan2
- TSHZ2 | c.616G>A p.G206R | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777285955, COSV61590486; called by muse, varscan2
- TUBA3C | c.661C>T p.R221C | Missense Mutation (SNP) | VAF 59/241 reads (24%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.103); catalogued as rs943568205, COSV67138798; called by muse, mutect2, varscan2
- TULP4 | c.296C>T p.T99M | Missense Mutation (SNP) | VAF 118/419 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs937565993, COSV65579233; called by muse, mutect2, varscan2
- UBL4A | c.163C>T p.R55* | Nonsense Mutation (SNP) | VAF 38/181 reads (21%) | catalogued as COSV54837023; called by muse, mutect2, varscan2
- UNC5CL | c.796C>T p.R266C | Missense Mutation (SNP) | VAF 42/167 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.635); catalogued as rs773491669, COSV55111301; called by muse, mutect2, varscan2
- UPP2 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 70/272 reads (26%) | SIFT tolerated (0.3); PolyPhen benign (0.121); catalogued as rs371644480; called by muse, mutect2, varscan2
- VPS26C | c.376C>T p.R126W | Missense Mutation (SNP) | VAF 50/255 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs367652803; called by muse, mutect2, varscan2
- VPS35L | c.1442A>T p.D481V | Missense Mutation (SNP) | VAF 20/311 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.663); catalogued as COSV51988566; called by muse, mutect2
- VPS50 | c.853G>A p.V285M | Missense Mutation (SNP) | VAF 150/863 reads (17%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.921); catalogued as rs755082195, COSV52493024; called by muse, mutect2, varscan2
- XIRP2 | c.7900G>A p.G2634R (on ENST00000628543; = p.G2809R on NM_152381.6) | Missense Mutation (SNP) | VAF 34/114 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.017); catalogued as rs1412549174, COSV54704403, COSV99741308; called by muse, mutect2, varscan2
- YLPM1 | c.5477C>T p.P1826L | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs776882142, COSV53117540; called by muse, mutect2, varscan2
- YTHDF1 | c.152T>C p.M51T | Missense Mutation (SNP) | VAF 42/180 reads (23%) | SIFT tolerated (0.16); PolyPhen benign (0.024); catalogued as COSV64833460; called by muse, mutect2, varscan2
- ZBTB20 | c.935G>A p.R312H (on ENST00000474710 / NM_001164342.2; = p.R239H on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV61862359; called by muse, varscan2
- ZBTB20 | c.818C>T p.A273V (on ENST00000474710 / NM_001164342.2; = p.A200V on NM_015642.6 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.117); catalogued as COSV61862367; called by muse, mutect2, varscan2
- ZBTB21 | c.402dup p.V135Sfs*6 | Frame Shift Ins (INS) | VAF 43/165 reads (26%) | catalogued as rs796812009; called by mutect2, varscan2
- ZC3H18 | c.670T>C p.C224R | Missense Mutation (SNP) | VAF 53/211 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.788); catalogued as COSV56326950; called by muse, mutect2, varscan2
- ZFR | c.3070C>T p.R1024C | Missense Mutation (SNP) | VAF 141/559 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54050538; called by muse, mutect2, varscan2
- CCDC88B | c.2870A>G p.Q957R | Missense Mutation (SNP) | VAF 14/80 reads (18%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.932); called by muse, mutect2
- CNTLN | c.3767C>T p.A1256V | Missense Mutation (SNP) | VAF 12/284 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2
- CNTN5 | c.2473dup p.M825Nfs*6 | Frame Shift Ins (INS) | VAF 43/188 reads (23%) | called by mutect2, pindel, varscan2
- DBN1 | c.292dup p.C98Lfs*7 | Frame Shift Ins (INS) | VAF 10/47 reads (21%) | called by mutect2, pindel, varscan2
- GAPDH | c.95C>T p.A32V | Missense Mutation (SNP) | VAF 13/361 reads (4%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.031); called by muse, mutect2
- MAGEB1 | c.113G>A p.C38Y | Missense Mutation (SNP) | VAF 7/60 reads (12%) | SIFT tolerated (1); PolyPhen benign (0.236); called by muse, varscan2
- MAGEE2 | c.1312C>T p.H438Y | Missense Mutation (SNP) | VAF 12/184 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.378); called by muse, mutect2
- NBPF15 | c.1792G>T p.V598L | Missense Mutation (SNP) | VAF 108/248 reads (44%) | SIFT tolerated (0.1); PolyPhen benign (0.312); called by muse, mutect2, varscan2
- NHS | c.4253G>A p.R1418Q | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- NRXN3 | c.315G>T p.R105S (on ENST00000557594 / NM_001272020.2; = p.R737S on NM_004796.6) | Missense Mutation (SNP) | VAF 8/134 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); called by muse, mutect2
- PCDHB15 | c.683T>A p.I228N | Missense Mutation (SNP) | VAF 8/124 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); called by muse, mutect2
- POLR2A | c.1091G>A p.R364H | Missense Mutation (SNP) | VAF 10/262 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- SLIT2 | c.4585T>C p.S1529P | Missense Mutation (SNP) | VAF 10/196 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.328); called by muse, mutect2
- SSH3 | c.1015G>T p.G339C | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- TMCC1 | c.1241G>A p.S414N (on ENST00000393238 / NM_001349268.2; = p.S90N on NM_015008.5 and 6 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/308 reads (3%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2
- ACADL | c.1116A>G p.A372= | Silent (SNP) | VAF 44/189 reads (23%) | catalogued as COSV52054745; called by muse, mutect2, varscan2
- ACTL7A | c.606G>A p.S202= | Silent (SNP) | VAF 26/117 reads (22%) | catalogued as rs377392593; called by muse, mutect2, varscan2
- BAHCC1 | c.5625G>A p.S1875= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs371234536; called by muse, mutect2, varscan2
- BAIAP2L1 | c.858C>T p.P286= | Silent (SNP) | VAF 106/641 reads (17%) | catalogued as rs200900587, COSV50058748; called by muse, mutect2, varscan2
- BAZ1B | c.1140T>C p.T380= | Silent (SNP) | VAF 86/679 reads (13%) | catalogued as COSV59993211; called by muse, varscan2
- BPIFC | c.1515A>G p.S505= | Silent (SNP) | VAF 38/158 reads (24%) | catalogued as COSV53279953; called by muse, mutect2, varscan2
- CASTOR2 | c.384C>T p.R128= | Silent (SNP) | VAF 113/1086 reads (10%) | called by muse, mutect2, varscan2
- CATSPER1 | c.1422C>T p.I474= | Silent (SNP) | VAF 14/77 reads (18%) | catalogued as COSV56412701; called by muse, varscan2
- CCDC105 | c.879C>T p.C293= | Silent (SNP) | VAF 16/63 reads (25%) | catalogued as COSV52963298; called by muse, mutect2, varscan2
- CDH6 | c.2121C>T p.R707= | Silent (SNP) | VAF 27/127 reads (21%) | catalogued as rs764986629, COSV54075598; called by muse, mutect2, varscan2
- CELSR1 | c.4959C>T p.C1653= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs768793888, COSV53096621; called by muse, varscan2
- COL6A3 | c.4662C>T p.D1554= | Silent (SNP) | VAF 45/99 reads (45%) | catalogued as rs764225803, COSV55102308; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CPA1 | c.1164C>T p.G388= | Silent (SNP) | VAF 8/198 reads (4%) | called by muse, mutect2
- CPEB4 | c.12C>T p.Y4= | Silent (SNP) | VAF 13/90 reads (14%) | catalogued as COSV54174914; called by muse, mutect2, varscan2
- DHRS9 | c.600C>T p.H200= | Silent (SNP) | VAF 57/341 reads (17%) | catalogued as rs761781142, COSV59141072; called by muse, mutect2, varscan2
- DMBT1 | c.1659A>G p.S553= | Silent (SNP) | VAF 31/185 reads (17%) | called by muse, mutect2, varscan2
- DTX2 | c.381C>T p.S127= | Silent (SNP) | VAF 14/111 reads (13%) | catalogued as rs532528346, COSV56863913; called by muse, mutect2, varscan2
- EHHADH | c.528C>T p.D176= | Silent (SNP) | VAF 29/690 reads (4%) | catalogued as COSV51632241; called by muse, mutect2
- EIPR1 | c.870G>A p.T290= | Silent (SNP) | VAF 23/78 reads (29%) | catalogued as rs761019969, COSV66132065, COSV66133651; called by muse, mutect2, varscan2
- ELN | c.264G>A p.P88= | Silent (SNP) | VAF 23/145 reads (16%) | catalogued as rs782146064, COSV52709026; called by muse, mutect2, varscan2
- EPDR1 | c.567G>A p.T189= | Silent (SNP) | VAF 23/88 reads (26%) | catalogued as rs553553991, COSV52261286; called by muse, mutect2, varscan2
- EPPK1 | c.942C>T p.T314= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs544220184, COSV73260883; called by muse, mutect2
- FAM170B | c.288C>T p.C96= | Silent (SNP) | VAF 8/82 reads (10%) | catalogued as rs1387705107, COSV61253941; called by muse, mutect2
- FHL5 | c.756C>T p.C252= | Silent (SNP) | VAF 54/349 reads (15%) | catalogued as rs201145903, COSV58735884; called by muse, mutect2
- FLNA | c.3336C>T p.L1112= | Silent (SNP) | VAF 10/60 reads (17%) | catalogued as rs782418068, COSV100775025, COSV61048714; called by muse, mutect2, varscan2
- FLNC | c.7107C>T p.C2369= | Silent (SNP) | VAF 42/309 reads (14%) | catalogued as rs781154278, COSV57961659; ClinVar: likely benign; called by muse, mutect2, varscan2
- GREB1L | c.4710C>T p.P1570= | Silent (SNP) | VAF 19/79 reads (24%) | catalogued as rs181760697, COSV52552045; called by muse, mutect2, varscan2
- GUCY1B1 | c.315C>T p.H105= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs367583649; called by muse, mutect2, varscan2
- HASPIN | c.1107C>T p.T369= | Silent (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- IDS | c.57C>T p.S19= | Silent (SNP) | VAF 16/62 reads (26%) | catalogued as COSV61713735; called by muse, mutect2, varscan2
- IKZF3 | c.1074G>A p.E358= | Silent (SNP) | VAF 10/338 reads (3%) | called by muse, mutect2
- IRS4 | c.1668C>T p.H556= | Silent (SNP) | VAF 39/220 reads (18%) | catalogued as COSV64532615; called by muse, mutect2, varscan2
- KBTBD6 | c.393G>A p.T131= | Silent (SNP) | VAF 21/97 reads (22%) | catalogued as rs1360228779, COSV65271094; called by muse, mutect2, varscan2
- KBTBD7 | c.1089G>A p.S363= | Silent (SNP) | VAF 24/170 reads (14%) | catalogued as COSV65266955; called by muse, mutect2, varscan2
- KIF13B | c.4008G>A p.S1336= | Silent (SNP) | VAF 62/221 reads (28%) | catalogued as rs555633942, COSV101576036, COSV72954594; called by muse, mutect2, varscan2
- KLF9 | c.117T>C p.P39= | Silent (SNP) | VAF 6/41 reads (15%) | called by muse, mutect2, varscan2
- KLHL32 | c.552G>A p.T184= | Silent (SNP) | VAF 95/191 reads (50%) | catalogued as rs202093124, COSV65113937; called by muse, mutect2, varscan2
- KLRC1 | c.123G>A p.A41= | Silent (SNP) | VAF 214/950 reads (23%) | catalogued as rs562831230, COSV61725027; called by muse, mutect2, varscan2
- KNCN | c.33C>T p.R11= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as rs777275777, COSV53815315; called by muse, mutect2, varscan2
- KRT75 | c.648C>T p.T216= | Silent (SNP) | VAF 60/223 reads (27%) | catalogued as rs370097335; called by muse, mutect2, varscan2
- LAMB1 | c.4998C>T p.S1666= | Silent (SNP) | VAF 82/742 reads (11%) | catalogued as rs147490680, COSV55968853; called by muse, mutect2, varscan2
- LGALS4 | c.906G>A p.S302= | Silent (SNP) | VAF 28/100 reads (28%) | catalogued as rs755977666, COSV57044648; called by muse, mutect2, varscan2
- LOXL3 | c.1407C>T p.H469= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as rs568254745, COSV51211341; called by muse, mutect2, varscan2
- LRP1B | c.7332C>T p.S2444= | Silent (SNP) | VAF 95/381 reads (25%) | catalogued as rs376385168; called by muse, mutect2, varscan2
- LRRC37A | c.3762C>T p.G1254= | Silent (SNP) | VAF 12/30 reads (40%) | called by muse, mutect2, varscan2
- MED12L | c.4104A>G p.A1368= | Silent (SNP) | VAF 61/344 reads (18%) | catalogued as COSV56391009; called by muse, mutect2, varscan2
- MIGA1 | c.963C>T p.I321= | Silent (SNP) | VAF 70/267 reads (26%) | catalogued as rs753678013, COSV66222630; called by muse, varscan2
- MSLN | c.1614G>A p.A538= (on ENST00000382862 / NM_013404.4; = p.A530= on NM_005823.6) | Silent (SNP) | VAF 40/185 reads (22%) | catalogued as rs780202997, COSV53505020; called by muse, mutect2, varscan2
- MTMR7 | c.411G>A p.T137= | Silent (SNP) | VAF 132/511 reads (26%) | catalogued as rs140578144; called by muse, mutect2, varscan2
- MTOR | c.4113C>T p.P1371= | Silent (SNP) | VAF 20/124 reads (16%) | catalogued as COSV63876008; called by muse, mutect2, varscan2
- MXRA5 | c.6819C>T p.P2273= | Silent (SNP) | VAF 21/149 reads (14%) | catalogued as COSV54245096; called by muse, mutect2, varscan2
- MYOF | c.522G>A p.S174= | Silent (SNP) | VAF 49/236 reads (21%) | catalogued as rs752115954, COSV63707806; called by muse, mutect2, varscan2
- OR5K4 | c.756C>T p.Y252= | Silent (SNP) | VAF 79/215 reads (37%) | catalogued as rs752278724, COSV61584136; called by muse, mutect2, varscan2
- OTOL1 | c.507G>A p.P169= | Silent (SNP) | VAF 30/146 reads (21%) | catalogued as rs761346414, COSV60006977; called by muse, mutect2, varscan2
- PCDHGA5 | c.1533C>T p.T511= | Silent (SNP) | VAF 47/184 reads (26%) | catalogued as COSV54003381, COSV54046314; called by muse, mutect2, varscan2
- PDZRN3 | c.1080C>T p.T360= | Silent (SNP) | VAF 78/305 reads (26%) | catalogued as rs370653708; called by muse, mutect2, varscan2
- PER3 | c.2751T>C p.I917= | Silent (SNP) | VAF 19/102 reads (19%) | catalogued as COSV62707253; called by muse, mutect2, varscan2
- PHF7 | c.546A>G p.Q182= | Silent (SNP) | VAF 40/180 reads (22%) | catalogued as COSV59981354; called by muse, mutect2, varscan2
- PIK3R2 | c.336C>T p.P112= | Silent (SNP) | VAF 94/395 reads (24%) | catalogued as rs148843363; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PIP5K1C | c.1641G>A p.P547= | Silent (SNP) | VAF 20/116 reads (17%) | catalogued as rs756701195, COSV58949958; called by muse, mutect2, varscan2
- PSKH2 | c.312G>A p.A104= | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as rs569087166, COSV52612022; called by muse, mutect2, varscan2
- PSME4 | c.3324A>G p.Q1108= | Silent (SNP) | VAF 484/1096 reads (44%) | catalogued as rs1345595403, COSV66366820; called by muse, varscan2
- PTPN14 | c.2160G>A p.S720= | Silent (SNP) | VAF 15/53 reads (28%) | catalogued as rs369283606, COSV100872671; called by muse, mutect2, varscan2
- PTPN4 | c.1287C>T p.S429= | Silent (SNP) | VAF 96/425 reads (23%) | catalogued as rs752734592, COSV55306567; called by muse, mutect2, varscan2
- PTPRJ | c.177G>A p.T59= | Silent (SNP) | VAF 36/141 reads (26%) | catalogued as rs146294071; called by muse, mutect2, varscan2
- RTL1 | c.1341C>T p.Y447= | Silent (SNP) | VAF 7/32 reads (22%) | catalogued as COSV66017276; called by muse, mutect2, varscan2
- SCAF4 | c.39G>A p.S13= | Silent (SNP) | VAF 69/259 reads (27%) | catalogued as rs141072342; called by muse, mutect2, varscan2
- SCN5A | c.2613C>T p.S871= | Silent (SNP) | VAF 30/226 reads (13%) | catalogued as rs1403998634, CD024656, COSV61135806; called by muse, mutect2, varscan2
- SEC23IP | c.927C>T p.S309= | Silent (SNP) | VAF 66/281 reads (23%) | catalogued as rs766134801, COSV64832556; called by muse, mutect2, varscan2
- SENP6 | c.1032A>G p.R344= | Silent (SNP) | VAF 22/170 reads (13%) | catalogued as COSV59193199; called by muse, varscan2
- SFN | c.408C>T p.T136= | Silent (SNP) | VAF 24/98 reads (24%) | catalogued as rs774313113, COSV59433333; called by muse, mutect2, varscan2
- SH3PXD2A | c.1383G>A p.S461= (on ENST00000369774 / NM_001365079.1; = p.S433= on NM_014631.2) | Silent (SNP) | VAF 51/181 reads (28%) | catalogued as rs376589572; called by muse, mutect2, varscan2
- SLC25A2 | c.213T>C p.L71= | Silent (SNP) | VAF 5/99 reads (5%) | called by muse, mutect2
- SNRNP200 | c.1866T>C p.D622= | Silent (SNP) | VAF 13/79 reads (16%) | catalogued as rs1213752530, COSV60493098; called by muse, mutect2, varscan2
- SYT17 | c.282G>A p.S94= | Silent (SNP) | VAF 27/96 reads (28%) | catalogued as rs1329243818, COSV62547545; called by muse, mutect2, varscan2
- TBC1D2B | c.1182G>A p.T394= | Silent (SNP) | VAF 35/144 reads (24%) | catalogued as rs551759490, COSV56044996; called by muse, mutect2, varscan2
- TFCP2L1 | c.1287C>T p.I429= | Silent (SNP) | VAF 26/140 reads (19%) | catalogued as COSV55290641; called by muse, mutect2, varscan2
- TMEM79 | c.669G>A p.P223= | Silent (SNP) | VAF 17/83 reads (20%) | catalogued as rs752012005, COSV55294423; called by muse, mutect2, varscan2
- TTN | c.29595T>C p.P9865= (on ENST00000591111; = p.P8938= on NM_133378.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 26/516 reads (5%) | catalogued as rs1421342766, COSV60246058; called by muse, mutect2
- UPRT | c.420G>A p.A140= | Silent (SNP) | VAF 258/1064 reads (24%) | catalogued as rs772176065, COSV64912279; called by muse, varscan2
- VWA5A | c.612C>T p.T204= | Silent (SNP) | VAF 52/194 reads (27%) | catalogued as rs569247598, COSV63708029; called by muse, mutect2, varscan2
- VWF | c.399C>T p.A133= | Silent (SNP) | VAF 81/194 reads (42%) | catalogued as COSV54629915; called by muse, mutect2, varscan2
- WSCD2 | c.138G>A p.S46= | Silent (SNP) | VAF 12/64 reads (19%) | catalogued as rs764081584, COSV54581381, COSV54588548; called by muse, mutect2, varscan2
- ZNF101 | c.417G>A p.T139= | Silent (SNP) | VAF 28/105 reads (27%) | catalogued as rs772867645, COSV58908834; called by muse, mutect2, varscan2
- ZNF445 | c.2025C>T p.P675= | Silent (SNP) | VAF 26/169 reads (15%) | catalogued as rs138400939; called by muse, mutect2, varscan2
- ZNF660 | c.219G>A p.T73= | Silent (SNP) | VAF 36/180 reads (20%) | catalogued as rs899558649, COSV59548974; called by muse, mutect2, varscan2
- ZNF836 | c.2709A>G p.S903= | Silent (SNP) | VAF 140/544 reads (26%) | catalogued as COSV59085179; called by muse, mutect2, varscan2
- ZNF84 | c.924G>A p.S308= | Silent (SNP) | VAF 112/332 reads (34%) | catalogued as rs1021191098, COSV59654582; called by muse, mutect2, varscan2
- ZSWIM8 | c.3069G>A p.T1023= (on ENST00000605216 / NM_001242487.2; = p.T1028= on NM_015037.3) | Silent (SNP) | VAF 23/128 reads (18%) | catalogued as COSV67133936; called by muse, mutect2, varscan2
- ANXA2 | c.*10C>T | 3'UTR (SNP) | VAF 53/170 reads (31%) | catalogued as rs766683667, COSV60317578; called by muse, mutect2, varscan2
- ATXN2L | c.*189A>G | 3'UTR (SNP) | VAF 40/162 reads (25%) | catalogued as COSV57376811; called by muse, varscan2
- BNIP3L | c.*26C>T | 3'UTR (SNP) | VAF 8/212 reads (4%) | catalogued as rs1214697634; called by muse, mutect2
- C11orf40 | n.423G>A | RNA (SNP) | VAF 76/295 reads (26%) | catalogued as rs142861848; called by muse, mutect2, varscan2
- DCHS2 | n.8563G>A | RNA (SNP) | VAF 31/147 reads (21%) | catalogued as rs376262021; called by muse, mutect2, varscan2
- DSCR4 | n.445G>A | RNA (SNP) | VAF 146/888 reads (16%) | catalogued as rs182817600; called by muse, varscan2
- MARVELD3 | chr16:71640700 G>A | 3'Flank (SNP) | VAF 41/97 reads (42%) | catalogued as rs901751702, COSV51705536; called by muse, mutect2, varscan2
- MC3R | c.-44G>A | 5'UTR (SNP) | VAF 53/240 reads (22%) | catalogued as COSV54764647; called by muse, mutect2, varscan2
- R3HDML | chr20:44355821 C>T | 3'Flank (SNP) | VAF 18/53 reads (34%) | catalogued as rs1051122101, COSV53837238; called by muse, mutect2, varscan2
- VPS11 | c.-1115G>A | 5'UTR (SNP) | VAF 59/234 reads (25%) | catalogued as COSV56186541; called by muse, mutect2, varscan2
